MMRF case MMRF_2608 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/546debb0-ca49-46a1-ab23-0c06c8241edc

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.5 years (24,643 days); ISS stage: I; Days to last known disease status: 629 days (1.7 years); Days to last follow up: 629 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 33 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 4 days; Days to treatment end: 105 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 44 days; Days to treatment end: 326 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 168 days; Days to treatment end: 326 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 629.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0: M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 232 mg/dL; Immunoglobulin G 9.51 g/L; Immunoglobulin A 1.26 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 0.7 µg/mL; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 9.4 ×10⁹/L; Absolute Neutrophil 5.17 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 265 µmol/L; Blood Urea Nitrogen 15 mmol/L; Calcium 2.13 mmol/L; Albumin 43 g/L; Total Protein 7.3 g/dL; Glucose 5.23 mmol/L; C-Reactive Protein 0.11 mg/dL.
- Day 103: Serum Free Immunoglobulin Light Chain, Kappa 0.698 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.73 mg/dL; Immunoglobulin G 3.52 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.07 g/L; Hemoglobin 5.83 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.14 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 5 mmol/L.
- Day 168 (ECOG 2): Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L.
- Day 272: Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.37 mg/dL; Immunoglobulin G 5.69 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.07 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.88 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.57 mmol/L; Glucose 5.39 mmol/L.
- Day 335: Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.05 mg/dL; Immunoglobulin G 6.2 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.51 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.53 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 5.8 g/dL.
- Day 433: Serum Free Immunoglobulin Light Chain, Kappa 2.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.5 mg/dL; Immunoglobulin G 9.24 g/L; Immunoglobulin A 1.2 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 3.58 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.29 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 14.6 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL.
- Day 608 (ECOG 3): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.15 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 2.05 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.78 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 9 mmol/L; Calcium 2.15 mmol/L; Total Protein 6.4 g/dL.

Other clinical attributes
- Day 0: Weight: 102 kg; Height: 176 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2608_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_2608_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
